TCGA case TCGA-AO-A12D — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2fe854b4-bac9-4801-9a1c-ee99388e8082

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 43.2 years (15,774 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1c; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 16; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 65 days; Days to treatment end: 128 days; Number of cycles: 4; Treatment dose: 3,984 mg; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Days to treatment start: 65 days; Days to treatment end: 128 days; Number of cycles: 4; Treatment dose: 400 mg; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 149 days; Days to treatment end: 212 days; Number of cycles: 4; Treatment dose: 1,728 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 170 days; Days to treatment end: 503 days (1.4 years); Number of cycles: 17; Prescribed dose: 6; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 282 days; Days to treatment end: 316 days; Treatment dose: 10,000 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (3 entries)
- Days to follow up: 1,948 days (5.3 years); Disease response: Tumor Free.
- Days to follow up: 2,515 days (6.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 2,151.

Molecular and laboratory tests
- ERBB2 (FISH): 6.7; Cell count: 32; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 441; Cell count: 32.
- ERBB2 (IHC): Positive; Staining intensity value: 3+; Test value range: 90-99%.
- ERBB2 amplification (FISH): Positive.
- ESR1 (IHC): Negative; Test value range: <10%.
- PGR (IHC): Negative; Test value range: <10%.
- Test (FISH): Copy Number Reported; Copy number: 66; Cell count: 32.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A12D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 750 mg.
  Slide TCGA-AO-A12D-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A12D-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A12D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A12D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 6.7; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Her2 IHC score: 3+; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 0; Her2 positivity method text: 3+ Positive; Her2 fish method: >=2.0 Positive; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant; Anatomic organ subdivision: Left.
- Follow-up form 2: New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 2.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Albumin-Bound Paclitaxel.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,515 days; disease-specific survival: no event (censored), 2,515 days; disease-free interval: no event (censored), 2,515 days; progression-free interval: no event (censored), 2,515 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A12D-01A-11D-A111-01): tumor purity 0.3, ploidy 3.4, whole-genome doublings 1.
